CGCI case BLGSP-71-30-00640 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3247dd06-161e-4306-a3c5-9b4d4531422a

Demographics
Sex at birth: male; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Burkitt lymphoma, NOS (Includes all variants) (the primary disease): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 53.2 years (19,439 days); Year of diagnosis: 2005; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,149 days (14.1 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Thyroid; Sites of involvement: Thyroid / Cerebrospinal fluid.
   Pathology details: Bone marrow malignant cells: No; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: IVAC; Days to treatment start: 4 days; Days to treatment end: 17 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 4 days; Days to treatment end: 17 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 4 days; Days to treatment end: 17 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Initial disease status: Initial Diagnosis; Days to treatment start: 79 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.
2. Tumor, NOS: Tissue or organ of origin: Skin of lower limb and hip; Classification of tumor: Synchronous primary; Age at diagnosis: 64.1 years (23,424 days); Days to diagnosis: 3,985 days (10.9 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 3,985 days (10.9 years); Disease response: Tumor Free.
- Days to follow up: 5,149 days (14.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 666.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- Test (IHC): Positive; Specialized molecular test: kappa.
- Lactate Dehydrogenase 144 [Blood test normal range upper: 210].

Other clinical attributes
- Day 0: Weight: 79.5 kg; Height: 175 cm; BMI: 26.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00640-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00640-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00640-01-EBER: Tissue microarray coordinates: G1,H1.
  Slide BLGSP-71-30-00640-01-BCL2: Tissue microarray coordinates: G1,H1.
  Slide BLGSP-71-30-00640-01-CD10: Tissue microarray coordinates: G1,H1.
  Slide BLGSP-71-30-00640-01-CD3: Tissue microarray coordinates: G1,H1.
  Slide BLGSP-71-30-00640-01-CD20: Tissue microarray coordinates: G1,H1.
  Slide BLGSP-71-30-00640-01-Ki67: Tissue microarray coordinates: G1,H1.
  Slide BLGSP-71-30-00640-01-BCL6: Tissue microarray coordinates: G1,H1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Cerebrospinal Fluid.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 144; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: kappa.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Skin right thigh; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: skin - right thigh BCC; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP-R, intrathecal methotrexate, intrathecal cytarabine, IVAC; Pharma adjuvant cycles count: 2.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Stem Cell Transplant; Stem cell transplantation: Autologous.
